Gene-level copy-number profile of tumor specimen C3N-00203-03 from CPTAC case C3N-00203, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.2 years (26,353 days).
Specimen C3N-00203-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7de18499-aa7b-408a-a9c6-062c5a15568e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00203-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,745 have no estimate.
https://portal.gdc.cancer.gov/files/43a237e9-7aa3-4f83-83ab-79b62a16ba9b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 22; copy number 1: 654; copy number 2: 11,574; copy number 3: 14,688; copy number 4: 22,385; copy number 5: 4,645; copy number 6: 2,943; copy number 7: 727; copy number 8: 783; copy number 9: 234; copy number 10: 83; copy number 11: 83; copy number 12: 2; copy number 13: 43; copy number 14: 12.

Homozygous deletions (total copy number 0; autosomes only): 22 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:148,458,814–148,750,099, 7 genes (within-gene range 0–3): AC245100.7, PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B.
- chr1:196,850,283–196,918,713, 2 genes (within-gene range 0–3): BX248415.1, CFHR4.
- chr16:30,182,827–30,254,510, 11 genes: CORO1A, AC012645.3, BOLA2B, SLX1A, SLX1A-SULT1A3, SULT1A3, AC106782.1, AC106782.6, AC106782.3, AC106782.2, NPIPB13.
- chr16:32,356,981–32,380,049, 2 genes: AC133548.1, ACTR3BP3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 391 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:200,253,419–200,483,604, 6 genes, copy number 10: LINC00862, AC097065.2, AC097065.1, AC104461.1, ZNF281, AL359834.1.
- chr2:10,570,754–10,689,987, 1 gene, copy number 11 (within-gene range 7–11): NOL10.
- chr2:10,690,344–11,348,330, 18 genes, copy number 11 (within-gene range 4–11): RN7SL832P, Metazoa_SRP, AC092687.2, ATP6V1C2, RNU7-138P, AC092687.3, PDIA6, RNU7-176P, LINC01954, AC092687.1, AC079587.1, KCNF1, RPL6P4, AC062028.1, C2orf50, SLC66A3, ROCK2, RNU6-1081P.
- chr2:167,954,020–170,120,098, 33 genes, copy number 9: STK39, PHF5GP, RN7SL813P, CERS6, MIR4774, RNU6-766P, CERS6-AS1, NOSTRIN, SPC25, G6PC2, ABCB11, DHRS9, AC007556.1, UBE2V1P6, LRP2, BBS5, AC093899.2, KLHL41, FASTKD1, AC093899.1, PPIG, CCDC173, AC016772.1, PHOSPHO2, KLHL23, AC009967.1, PTCHD3P2, CYB5AP2, SSB, METTL5, UBR3, NSA2P5, RNU6-1006P.
- chr2:176,495,255–176,819,180, 1 gene, copy number 10 (within-gene range 6–10): LINC01117.
- chr2:176,629,572–176,930,090, 8 genes, copy number 10: LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P.
- chr3:169,821,922–169,869,935, 2 genes, copy number 10: LRRIQ4, LRRC31.
- chr7:97,598,933–97,599,260, 1 gene, copy number 14: RN7SKP104.
- chr7:105,110,704–105,600,875, 13 genes, copy number 9 (within-gene range 6–9): SRPK2, AC005070.1, AC005070.2, AC004884.1, RWDD4P1, AC004884.2, RNU6-1322P, PUS7, AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2.
- chr7:115,647,461–118,496,171, 57 genes, copy number 9–13: AC092590.1, AC093714.1, AC093714.2, Y_RNA, TFEC, AC073130.3, TES, AC073130.2, AC002066.1, AC073130.1, CAV2, Metazoa_SRP, CAV1, AC006159.1, AC006159.2, COMETT, MET, CAPZA2, AC002543.1, Y_RNA, RNA5SP239, ST7-AS1, AC106873.5, AC106873.7, ST7, ST7-OT4, AC106873.8, AC106873.3, AC106873.2, AC106873.6, AC106873.4, AC106873.1, TPM3P1, MIR6132, ST7-AS2, AC002542.6, AC002542.2, AC002542.3, AC002542.1, AC002542.5, AC002542.4, AC006326.1, MTND4P6, MTCYBP6, WNT2, CFTR, ASZ1, ANKRD49P4, AC000111.2, CFTR-AS1, AC000111.1, AC000061.1, CTTNBP2, AC007568.1, AC003084.1, LSM8, ANKRD7.
- chr7:127,580,628–128,092,609, 7 genes, copy number 9 (within-gene range 6–9): GCC1, ARF5, FSCN3, PAX4, AC073934.1, SND1, AC006529.1.
- chr7:128,524,016–128,669,892, 13 genes, copy number 11: AC090114.2, AC090114.3, AC090114.1, AC108010.1, AC018638.8, RNU6-177P, AC018638.4, AC018638.2, AC018638.1, AC018638.5, CICP14, AC018638.7, AC018638.3.
- chr7:148,637,179–155,812,463, 177 genes, copy number 9–14 (broad region; genes not listed).
- chr8:128,150,116–128,220,803, 2 genes, copy number 10: MIR1208, RN7SKP226.
- chr9:64,737,403–64,765,535, 2 genes, copy number 12: AL359955.2, IGKV1OR-2.
- chr9:65,189,995–65,230,861, 3 genes, copy number 13: BMS1P12, AL512605.1, AL512605.2.
- chr10:75,003,055–75,236,030, 10 genes, copy number 9 (within-gene range 4–9): AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1.
- chr10:75,269,392–75,269,545, 1 gene, copy number 9: RPL39P25.
- chr10:125,784,980–125,896,436, 6 genes, copy number 9: UROS, MIR4484, BCCIP, DHX32, Metazoa_SRP, RNU2-42P.
- chr12:57,055,643–57,132,139, 3 genes, copy number 9 (within-gene range 4–9): NEMP1, NAB2, STAT6.
- chr13:81,018,176–81,044,691, 1 gene, copy number 9: LINC00377.
- chr19:19,757,366–19,895,847, 11 genes, copy number 9: LINC00663, AC011477.8, AC011477.3, AC011477.4, ZNF56, ZNF506, AC011477.1, BNIP3P9, ZNF253, BNIP3P10, AC011477.2.
- chr19:36,379,351–36,727,701, 15 genes, copy number 9 (within-gene range 4–9): AC092296.4, ZFP82, AC092296.3, ZNF566, AC092295.2, CTBP2P7, ZNF260, AC092295.1, ZNF529, ZNF529-AS1, ZNF382, ZNF461, AC074138.1, LINC01534, ZNF567.

Autosomal genes at a single copy (total copy number 1): 654. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
